Gene-level copy-number profile of tumor specimen ALCH-AER1-TTP1-A from ALCHEMIST case ALCH-AER1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.6 years (26,525 days).
Specimen ALCH-AER1-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1e601dff-7f42-45e8-887a-42481ad95d9e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AER1-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/51efb8b0-c322-4c31-9d4c-8cafd24188ff

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 342; copy number 1: 20,159; copy number 2: 31,636; copy number 3: 3,674; copy number 4: 2,155; copy number 5: 347; copy number 6: 27; copy number 7: 3; copy number 9: 54.

Homozygous deletions (total copy number 0; autosomes only): 342 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:176,077,472–176,188,958, 14 genes (within-gene range 0–1): EVX2, HOXD13, HOXD12, HOXD11, HOXD10, HOXD-AS2, HOXD9, HOXD8, HOXD3, MIR10B, HOXD4, HAGLR, AC009336.1, HAGLROS.
- chr2:232,343,116–232,421,461, 9 genes (within-gene range 0–1): NRBF2P6, ECEL1P3, AC068134.3, ALPP, AC068134.1, ECEL1P2, ALPG, ECEL1P1, AC068134.2.
- chr5:180,967,189–180,982,611, 3 genes: AC091874.2, AC091874.1, ARPP19P1.
- chr7:63,768,257–63,771,047, 1 gene: CICP24.
- chr8:22,578,279–22,604,150, 3 genes: PDLIM2, AC037459.1, C8orf58.
- chr9:470,291–746,106, 1 gene (within-gene range 0–1): KANK1.
- chr9:547,135–15,544,294, 188 genes (broad region; genes not listed).
- chr9:15,588,355–15,588,615, 1 gene (within-gene range 0–1): HMGN2P16.
- chr10:124,004,304–124,004,828, 1 gene: AL683842.1.
- chr11:2,771,356–2,925,246, 7 genes (within-gene range 0–1): COX6CP18, KCNQ1-AS1, KCNQ1DN, AC013791.1, CDKN1C, SLC22A18AS, SLC22A18.
- chr11:3,000,922–3,166,739, 6 genes: CARS1, CARS1-AS1, RNU1-91P, AC108448.3, AC108448.2, OSBPL5.
- chr11:28,261,194–28,519,341, 4 genes (within-gene range 0–2): RN7SKP158, AC104978.1, MIR8068, AC013714.1.
- chr13:113,815,630–114,132,623, 10 genes (within-gene range 0–1): GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, RASA3, RASA3-IT1.
- chr14:102,539,644–102,539,726, 1 gene: MIR4309.
- chr15:19,878,555–20,291,586, 22 genes: AC138701.1, RNU6-978P, AC138701.2, AC127381.2, IGHV1OR15-9, SLC20A1P3, IGHV1OR15-2, IGHV3OR15-7, IGHD5OR15-5A, IGHD4OR15-4A, IGHD3OR15-3A, IGHD2OR15-2A, IGHD1OR15-1A, FAM30B, AC127381.1, BCAR1P1, RN7SL584P, AC087386.1, AC087386.2, BMS1P15, RHPN2P1, CHEK2P2.
- chr15:25,255,579–25,268,551, 4 genes (within-gene range 0–1): AC124303.1, SNORD115-45, SNORD115-46, SNORD115-47.
- chr15:31,215,622–31,435,665, 4 genes (within-gene range 0–1): LINC02352, AC012236.1, KLF13, UBE2CP4.
- chr15:41,828,092–41,848,155, 3 genes (within-gene range 0–1): JMJD7, JMJD7-PLA2G4B, PLA2G4B.
- chr15:41,851,913–41,866,551, 2 genes (within-gene range 0–1): RNA5SP393, MIR4310.
- chr15:75,186,651–75,234,834, 5 genes: RPL36AP45, C15orf39, AC113208.4, AC113208.5, AC113208.3.
- chr15:77,613,027–77,820,900, 5 genes: LINGO1, LINGO1-AS1, LINGO1-AS2, AC105133.2, AC105133.1.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr17:3,896,592–3,981,899, 3 genes: P2RX1, ATP2A3, LINC01975.
- chr17:4,897,771–4,949,061, 6 genes (within-gene range 0–1): CHRNE, C17orf107, GP1BA, SLC25A11, RNF167, PFN1.
- chr17:18,225,635–18,244,875, 1 gene (within-gene range 0–1): LLGL1.
- chr18:37,243,040–37,762,131, 8 genes (within-gene range 0–1): CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1, MIR4318, RPL12P40.
- chr19:34,481,758–34,512,304, 1 gene: WTIP.
- chr19:58,451,611–58,605,223, 20 genes: ZNF324B, ZNF324, ZNF446, AC012313.7, SLC27A5, RNU6-1337P, RN7SL693P, AC012313.9, ZBTB45, RN7SL525P, TRIM28, MIR6807, CHMP2A, UBE2M, MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1, AC016629.2.
- chr21:8,603,547–8,603,984, 1 gene: RPSAP68.
- chr22:18,773,665–18,843,399, 3 genes: GGT3P, AC008132.2, E2F6P1.
- chr22:41,922,032–41,926,806, 2 genes: TNFRSF13C, MIR378I.
- chr22:49,718,053–49,724,506, 1 gene: AL023802.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 431 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:1,309,310–1,309,377, 1 gene, copy number 7: MIR4457.
- chr7:54,330,670–55,878,164, 39 genes, copy number 5: LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2.
- chr8:41,261,962–43,674,591, 80 genes, copy number 5–9 (broad region; genes not listed).
- chr8:78,516,340–85,284,073, 105 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:141,117,278–145,066,685, 186 genes, copy number 5 (broad region; genes not listed).
- chr9:60,914,407–61,627,683, 14 genes, copy number 5: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D.
- chr16:975,761–981,596, 1 gene, copy number 5 (within-gene range 2–5): CEROX1.
- chr17:32,876,759–32,945,106, 3 genes, copy number 6 (within-gene range 4–6): AC084809.1, AC084809.2, TMEM98.
- chr22:18,873,543–18,894,407, 2 genes, copy number 7: FAM230F, AC008103.1.

Autosomal genes at a single copy (total copy number 1): 19,136. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
